Somatic mutation profile of tumor specimen MP2PRT-PAULUX-TMP1-A (aliquot MP2PRT-PAULUX-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAULUX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,251 days).
Specimen MP2PRT-PAULUX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a62e8f1-b398-4e74-826b-5f4a077b08c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAULUX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAULUX-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81fca1a4-5334-4c80-80d1-5bedb52e51a3

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, 3'Flank 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBL | c.1096-1G>T p.X366_splice | Splice Site (SNP) | VAF 44/130 reads (34%) | catalogued as rs397517076, CD1314297, CS099550, CS150637, COSV50631547, COSV50635311, COSV50641081; ClinVar: pathogenic; called by muse, varscan2
- ADAM18 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 28/365 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.048); catalogued as rs764655233, COSV99696195; called by muse, mutect2
- CDCP2 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 199/426 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs562185443, COSV61286014; called by muse, mutect2, varscan2
- CFAP221 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 90/183 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as rs570718788, COSV54655096; called by muse, mutect2, varscan2
- MICU3 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs369698557; called by muse, varscan2
- TPTE | c.587T>C p.L196P (on ENST00000618007 / NM_199261.4; = p.L178P on NM_199259.4) | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs771358886; called by muse, mutect2, varscan2
- WIZ | c.4892C>G p.S1631C (on ENST00000673675 / NM_001371589.1; = p.S536C on NM_021241.3) | Missense Mutation (SNP) | VAF 84/183 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs1184932333; called by muse, mutect2, varscan2
- ABCA1 | c.4266C>G p.N1422K | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRQ | c.4949A>C p.Y1650S (on ENST00000616559; = p.Y1608S on NM_001145026.2) | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TNRC6B | c.4256dup p.N1419Kfs*9 (on ENST00000454349 / NM_001162501.2; = p.N1309Kfs*9 on NM_015088.3) | Frame Shift Ins (INS) | VAF 90/221 reads (41%) | called by mutect2, pindel, varscan2
- IGLV4-69 | c.358_359insG p.*120R | Silent (INS) | VAF 58/149 reads (39%) | called by mutect2, pindel, varscan2
- RAD54L2 | c.99G>T p.V33= | Silent (SNP) | VAF 126/294 reads (43%) | catalogued as rs1302264311; called by muse, varscan2
- MIR1915 | chr10:21495858 G>C | 3'Flank (SNP) | VAF 222/494 reads (45%) | called by muse, mutect2, varscan2
